Somatic mutation profile of tumor specimen 1105200 (aliquot 7316UP-386-1105200) from CPTAC case C234192, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105200: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf71bb32-a628-44b4-a8c9-8d01f94b60c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105286 (Blood Derived Normal), aliquot 7316UP-386-1105286; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d45f4148-5a55-46e0-b986-c5baf13526f6

The open-access MAF lists 99 somatic variants for this specimen: 66 protein-altering or splice-affecting, 17 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 17, Intron 8, Nonsense Mutation 4, Frame Shift Del 3, Splice Region 3, Frame Shift Ins 2, 3'UTR 2, 5'UTR 2, RNA 2, 3'Flank 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 358/6208 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2
- AKR1B10 | c.742-7C>T | Splice Region (SNP) | VAF 45/380 reads (12%) | catalogued as rs766204329; called by muse, mutect2, varscan2
- AL592490.1 | c.923T>C p.I308T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs775154689; called by muse, mutect2, varscan2
- CCDC144A | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1365470382, COSV100501884; called by muse, mutect2, varscan2
- COL6A3 | c.2567G>A p.R856H | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs147897225, COSV55083041; called by muse, mutect2, varscan2
- DSCAML1 | c.5677G>A p.E1893K (on ENST00000321322; = p.E1833K on NM_020693.4) | Missense Mutation (SNP) | VAF 20/243 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1208211363; called by muse, mutect2
- EBPL | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.796); catalogued as rs200901347, COSV54431481; called by mutect2, varscan2
- GK2 | c.117C>A p.H39Q | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV62627486; called by muse, mutect2, varscan2
- IGHA1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 56/338 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs753985358; called by muse, mutect2, varscan2
- IGHG2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 62/438 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs762234471; called by muse, mutect2, varscan2
- ITGAM | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.18); catalogued as rs755777607, COSV54933096; called by muse, mutect2, varscan2
- KCNE1 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs142511345, CM097709; ClinVar: not provided / likely benign / uncertain significance / conflicting interpretations of pathogenicity; called by mutect2, varscan2
- LCN10 | c.536C>T p.A179V (on ENST00000474369 / NM_001368089.1; = p.A192V on NM_001001712.3) | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.266); catalogued as rs751195542; called by muse, mutect2, varscan2
- LRRTM4 | c.1606G>C p.G536R | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.235); catalogued as rs534581077; called by muse, mutect2, varscan2
- MAPK15 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 45/240 reads (19%) | catalogued as rs782012920; called by muse, mutect2, varscan2
- MUC16 | c.12422G>T p.G4141V | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.976); catalogued as rs1018086393; called by muse, mutect2, varscan2
- NLRP5 | c.62+1G>A p.X21_splice | Splice Site (SNP) | VAF 16/166 reads (10%) | catalogued as rs199475763; ClinVar: not provided; called by muse, mutect2, varscan2
- OR14A2 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as rs779547225; called by muse, mutect2, varscan2
- OR6F1 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs372005274, COSV57467846; called by muse, mutect2
- PDE10A | c.1105T>C p.Y369H | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.857); catalogued as COSV63050056; called by muse, mutect2
- PPARGC1B | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 75/409 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.91); catalogued as rs753410582; called by muse, mutect2, varscan2
- PTEN | c.122G>C p.R41T | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV64307058; called by muse, mutect2, varscan2
- RDH10 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 85/562 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs190882720, COSV53582156; called by muse, mutect2, varscan2
- SH3RF2 | c.1927G>A p.V643M | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1182882077; called by muse, mutect2, varscan2
- SLC1A6 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 60/459 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs1026402297, COSV55673390, COSV99693589; called by muse, mutect2, varscan2
- SSUH2 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 61/343 reads (18%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs147081374; called by muse, mutect2, varscan2
- STK32C | c.1119C>T p.N373= | Splice Region (SNP) | VAF 38/125 reads (30%) | catalogued as rs745931599; called by muse, mutect2, varscan2
- TIMD4 | c.239A>T p.K80M | Missense Mutation (SNP) | VAF 46/315 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs779272298; called by muse, mutect2, varscan2
- TOR4A | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV62627636; called by muse, mutect2, varscan2
- TPTE | c.1268C>T p.S423L (on ENST00000618007 / NM_199261.4; = p.S405L on NM_199259.4) | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs570468666; called by muse, mutect2
- WWC2 | c.2369C>G p.S790C | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs1237914404; called by muse, mutect2, varscan2
- ZBTB39 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.434); catalogued as COSV55630225; called by muse, mutect2, varscan2
- ZNF804A | c.51C>G p.H17Q | Missense Mutation (SNP) | VAF 42/325 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373088099; called by muse, mutect2, varscan2
- ZP2 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as rs558301595, COSV54814788; called by muse, mutect2, varscan2
- ADAMTS16 | c.3344C>T p.P1115L | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ADRA2C | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARFGEF3 | c.3235G>A p.V1079I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRAT1 | c.2339A>G p.D780G | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAPN2 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 38/322 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COX10 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- DNAH12 | c.3374G>T p.S1125I (on ENST00000351747; = p.S1148I on NM_001366028.2) | Missense Mutation (SNP) | VAF 47/299 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- DST | c.21967dup p.S7323Ffs*53 (on ENST00000361203 / NM_001374722.1; = p.S4996Ffs*22 on NM_015548.5) | Frame Shift Ins (INS) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- FASLG | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- FRAS1 | c.3284C>T p.T1095I | Missense Mutation (SNP) | VAF 39/310 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- GNAQ | c.397_400del p.K133Vfs*34 | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | called by mutect2, pindel, varscan2
- GNL2 | c.2096A>G p.Y699C | Missense Mutation (SNP) | VAF 71/329 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IWS1 | c.1801C>T p.Q601* | Nonsense Mutation (SNP) | VAF 21/103 reads (20%) | called by muse, mutect2, varscan2
- KCNT2 | c.3370G>A p.V1124I | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KHSRP | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- LHX5 | c.909G>T p.Q303H | Missense Mutation (SNP) | VAF 41/322 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MANSC1 | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- OR2A7 | c.607A>C p.I203L | Missense Mutation (SNP) | VAF 56/1395 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2
- OR5R1 | c.892A>G p.K298E | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCYT1A | c.123dup p.R42Tfs*8 | Frame Shift Ins (INS) | VAF 15/96 reads (16%) | called by mutect2, pindel, varscan2
- RNF17 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RYR2 | c.5906C>A p.P1969H | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SAMM50 | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLC6A17 | c.299del p.V100Gfs*7 | Frame Shift Del (DEL) | VAF 22/153 reads (14%) | called by mutect2, pindel, varscan2
- SYTL2 | c.1092G>C p.L364F | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- TMEM132C | c.3095G>A p.G1032E | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TTK | c.2310T>C p.C770= | Splice Region (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- UBN1 | c.1384_1385del p.K462Vfs*33 | Frame Shift Del (DEL) | VAF 19/174 reads (11%) | called by mutect2, pindel, varscan2
- UNC80 | c.4039C>T p.Q1347* | Nonsense Mutation (SNP) | VAF 36/258 reads (14%) | called by muse, mutect2, varscan2
- ZFPL1 | c.468G>A p.W156* | Nonsense Mutation (SNP) | VAF 34/164 reads (21%) | called by muse, mutect2, varscan2
- ZNF185 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- ZNF200 | c.59G>C p.R20T | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- ASB18 | c.639C>G p.R213= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- DLGAP3 | c.2166C>T p.A722= | Silent (SNP) | VAF 61/228 reads (27%) | catalogued as rs764770295; called by muse, mutect2, varscan2
- FAM172A | c.178C>T p.L60= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as COSV67936404; called by muse, mutect2, varscan2
- GNPTAB | c.1908G>A p.R636= | Silent (SNP) | VAF 43/210 reads (20%) | catalogued as COSV100172159; called by muse, mutect2, varscan2
- KANK3 | c.1839G>A p.A613= | Silent (SNP) | VAF 80/497 reads (16%) | catalogued as rs368061289, COSV58360783; called by muse, mutect2, varscan2
- KLK12 | c.564C>T p.G188= | Silent (SNP) | VAF 94/608 reads (15%) | catalogued as rs145723658; called by muse, mutect2, varscan2
- LRIT3 | c.1215C>G p.P405= | Silent (SNP) | VAF 49/263 reads (19%) | called by muse, mutect2, varscan2
- MTFR1 | c.576G>A p.P192= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as rs770323230; called by muse, mutect2
- MUC12 | c.5481A>G p.G1827= (on ENST00000379442; = p.G1684= on NM_001164462.1) | Silent (SNP) | VAF 18/456 reads (4%) | called by muse, mutect2
- OPLAH | c.864G>A p.S288= | Silent (SNP) | VAF 29/253 reads (11%) | catalogued as rs1554759938, COSV70679130; called by muse, mutect2, varscan2
- OR8J3 | c.838T>C p.L280= | Silent (SNP) | VAF 16/122 reads (13%) | called by muse, mutect2, varscan2
- SLC44A2 | c.1377C>T p.F459= | Silent (SNP) | VAF 31/272 reads (11%) | catalogued as COSV59834966; called by muse, mutect2, varscan2
- SON | c.2874A>C p.L958= | Silent (SNP) | VAF 30/166 reads (18%) | called by muse, mutect2, varscan2
- TRMT6 | c.567C>T p.A189= | Silent (SNP) | VAF 27/161 reads (17%) | catalogued as rs759809544; called by muse, mutect2, varscan2
- TTC6 | c.2556T>C p.D852= | Silent (SNP) | VAF 18/152 reads (12%) | catalogued as rs1363199747; called by muse, mutect2, varscan2
- USH2A | c.3735A>G p.R1245= | Silent (SNP) | VAF 61/182 reads (34%) | called by muse, mutect2, varscan2
- ZNFX1 | c.4287C>T p.V1429= | Silent (SNP) | VAF 55/315 reads (17%) | called by muse, mutect2, varscan2
- ABCC5 | c.3694+237G>A | Intron (SNP) | VAF 53/330 reads (16%) | catalogued as rs760020200; called by muse, mutect2, varscan2
- AIRE | c.*14G>A | 3'UTR (SNP) | VAF 72/435 reads (17%) | called by muse, mutect2, varscan2
- AP004607.5 | n.46G>C | RNA (SNP) | VAF 24/262 reads (9%) | catalogued as rs1169148690; called by muse, mutect2
- CD37 | c.343-174G>A | Intron (SNP) | VAF 17/119 reads (14%) | catalogued as rs1210480550; called by muse, mutect2, varscan2
- COBLL1 | c.344+70C>T | Intron (SNP) | VAF 6/58 reads (10%) | catalogued as rs754831585; called by muse, mutect2, varscan2
- CYP39A1 | c.*10G>C | 3'UTR (SNP) | VAF 14/63 reads (22%) | catalogued as rs1351642807; called by muse, mutect2
- DOCK4 | c.2736+3936C>T | Intron (SNP) | VAF 23/154 reads (15%) | called by muse, mutect2, varscan2
- LINC00479 | n.492C>T | RNA (SNP) | VAF 30/239 reads (13%) | called by muse, mutect2, varscan2
- MICAL1 | c.2305-47G>C | Intron (SNP) | VAF 19/225 reads (8%) | called by muse, mutect2
- RNU7-115P | chr17:64821949 C>T | 3'Flank (SNP) | VAF 86/606 reads (14%) | catalogued as rs755561023; called by muse, varscan2
- RPL27A | c.-1C>G | 5'UTR (SNP) | VAF 29/146 reads (20%) | catalogued as rs754250435; called by muse, mutect2, varscan2
- RPS21 | c.114+83G>A | Intron (SNP) | VAF 10/105 reads (10%) | catalogued as rs1422411816; called by muse, mutect2
- SPAG6 | c.-32G>C | 5'UTR (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- SPINK5 | c.475-411T>C | Intron (SNP) | VAF 22/143 reads (15%) | called by muse, mutect2, varscan2
- WDR49 | c.487-6642A>C | Intron (SNP) | VAF 15/97 reads (15%) | catalogued as COSV100393346; called by muse, mutect2, varscan2
- ZSWIM4 | chr19:13836439 C>T | 3'Flank (SNP) | VAF 15/135 reads (11%) | catalogued as rs759235923; called by muse, mutect2, varscan2
